Somatic mutation profile of tumor specimen MP2PRT-PATXSN-TBP1-A (aliquot MP2PRT-PATXSN-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PATXSN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,265 days).
Specimen MP2PRT-PATXSN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b8c4942-14ef-44b9-aab3-ebea490d5b2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATXSN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATXSN-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/969944a2-6153-4c1f-ac04-44e793619a42

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.2846A>T p.Y949F | Missense Mutation (SNP) | VAF 68/417 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV99710430; called by muse, mutect2, varscan2
- CCDC63 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as rs1363754749; called by muse, mutect2, varscan2
- DOCK1 | c.5434G>A p.G1812R | Missense Mutation (SNP) | VAF 91/503 reads (18%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.997); catalogued as rs201376871; called by muse, mutect2, varscan2
- FLT3 | c.1730A>C p.Q577P | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54056525; called by muse, mutect2, varscan2
- DCC | c.3219C>A p.S1073R | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- FLT3 | c.2510_2511delinsCCCTGAGC p.M837delinsTLS | In Frame Ins (INS) | VAF 56/281 reads (20%) | called by pindel, varscan2*
- IGKV1-27 | chr2:89213416 CAGTGGGA>AGGGGGAG | Missense Mutation (ONP) | VAF 33/132 reads (25%) | called by pindel, varscan2*
- IGKV2-30 | chr2:89244769 TACCACTGTGGGA>GGTTCTAGAG | Missense Mutation (DEL) | VAF 16/39 reads (41%) | called by pindel, varscan2*
- ITSN1 | c.3573C>A p.D1191E | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NELFA | c.746G>A p.R249Q (on ENST00000542778; = p.R238Q on NM_005663.5) | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, varscan2
- FLG | c.7596G>A p.S2532= | Silent (SNP) | VAF 66/460 reads (14%) | catalogued as rs142026832; called by muse, mutect2
- OR8B4 | c.861G>A p.S287= | Silent (SNP) | VAF 39/414 reads (9%) | catalogued as rs562146843, COSV62069661, COSV62069872; called by muse, mutect2
- TACC2 | c.2010G>T p.L670= | Silent (SNP) | VAF 96/538 reads (18%) | catalogued as COSV100551687; called by muse, mutect2, varscan2
